Somatic mutation profile of tumor specimen C3N-02754-01 (aliquot CPT0183850035) from CPTAC case C3N-02754, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 62.0 years (22,651 days).
Specimen C3N-02754-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e3acfe8-16e4-45de-8c29-5d7b81165cc1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02754-71 (Blood Derived Normal), aliquot CPT0183910002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/520d043d-a665-4a55-9c9f-4c742ba2a33f

The open-access MAF lists 29 somatic variants for this specimen: 20 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 6, Nonsense Mutation 2, RNA 1, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 38/524 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- STK11 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 21/246 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057520017, COSV58821219; ClinVar: likely pathogenic; called by muse, mutect2
- ADAM8 | c.1949C>T p.A650V | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.169); catalogued as rs201827043, COSV69864747; called by muse, mutect2
- DCHS2 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 42/696 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as rs1202050640; called by muse, mutect2
- EPHA6 | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs773107512, COSV67559447, COSV67572371; called by muse, mutect2, varscan2
- FPR1 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 45/265 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754232242, COSV59051992; called by muse, mutect2, varscan2
- SLCO3A1 | c.512C>T p.T171M | Missense Mutation (SNP) | VAF 31/642 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.166); catalogued as rs565500840; called by muse, mutect2
- SOGA1 | c.4943C>T p.S1648F | Missense Mutation (SNP) | VAF 15/203 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as COSV99412465; called by muse, mutect2
- TTN | c.14881G>A p.A4961T (on ENST00000591111; = p.A4034T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/197 reads (8%) | PolyPhen probably damaging (0.998); catalogued as rs754692422, COSV59861214, COSV60157889; called by muse, mutect2
- VEGFB | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 16/248 reads (6%) | catalogued as COSV100374919; called by muse, mutect2
- CCDC168 | c.14191T>A p.S4731T | Missense Mutation (SNP) | VAF 18/324 reads (6%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.725); called by muse, mutect2
- CRHBP | c.512C>T p.T171I | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2
- DOCK7 | c.1492G>A p.V498I | Missense Mutation (SNP) | VAF 14/276 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.387); called by muse, mutect2
- KIAA1109 | c.8510T>C p.V2837A | Missense Mutation (SNP) | VAF 12/378 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2
- MANBAL | c.246G>T p.K82N | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2
- MYO7A | c.4238T>C p.V1413A | Missense Mutation (SNP) | VAF 20/346 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- OTOP1 | c.1214C>G p.S405C | Missense Mutation (SNP) | VAF 24/316 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PTPRQ | c.1793C>T p.P598L (on ENST00000616559; = p.P556L on NM_001145026.2) | Missense Mutation (SNP) | VAF 32/486 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RBM10 | c.1957A>T p.K653* | Nonsense Mutation (SNP) | VAF 66/379 reads (17%) | called by muse, mutect2, varscan2
- SHC4 | c.1648G>C p.E550Q | Missense Mutation (SNP) | VAF 50/622 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2
- CUBN | c.3030G>A p.P1010= | Silent (SNP) | VAF 46/694 reads (7%) | catalogued as rs772693156; called by muse, mutect2
- CYTH4 | c.183G>A p.K61= | Silent (SNP) | VAF 20/252 reads (8%) | catalogued as COSV50633779; called by muse, mutect2
- DOCK2 | c.4596C>T p.N1532= | Silent (SNP) | VAF 26/249 reads (10%) | catalogued as rs372927020; ClinVar: likely benign; called by muse, mutect2
- FBXL16 | c.378C>A p.R126= | Silent (SNP) | VAF 11/107 reads (10%) | catalogued as rs376450820; called by muse, mutect2, varscan2
- FRK | c.399A>G p.S133= | Silent (SNP) | VAF 19/381 reads (5%) | called by muse, mutect2
- KRTAP20-2 | c.81T>C p.G27= | Silent (SNP) | VAF 77/1014 reads (8%) | catalogued as rs750366154, COSV58183475; called by muse, mutect2
- RN7SL495P | chr15:22608234 T>C | 3'Flank (SNP) | VAF 57/1069 reads (5%) | catalogued as rs768395513; called by muse, mutect2
- SERF2 | c.117-21C>T | Intron (SNP) | VAF 14/272 reads (5%) | catalogued as rs372561860; called by muse, mutect2
- SSPOP | n.12837G>A | RNA (SNP) | VAF 24/274 reads (9%) | catalogued as rs751859744; called by muse, mutect2
